Surgical pathology report (de-identified scan), TCGA case TCGA-29-2429, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-2429-01A (Primary Tumor).

[page 1 of 3]
TCGA-29-2429

Surg Path

CLINICAL HISTORY:

Abdominal, pelvic swelling.

GROSS EXAMINATION:

A. "Left gutter". Received is a 3 x 2 x 1 cm fragment of partially serosa covered with fibroadipose tissue. There is a 1.4 x 1.3 x 0.5 cm tan, papillary, serosa-based tumor. The tumor does not appear to invade through the serosa into the underlying soft tissue. Representative sections are submitted in block A1.

B. "Omentum". Received is a 5 x 5 x 3 cm fragment of fibroadipose tissue. A 0.6 cm in greatest dimension is firm nodule grossly consistent with lymph node is identified and submitted in block B1, along with representative adipose tissue.

C. "Omental tumor with small bowel". Received is a segment of small bowel (6 cm long, 2.5 cm in diameter) with a 3 cm long mesenteric attachment over its entire length. A 6.5 x 5 x 3 cm mass with lobulated, tan-white cut surface is connected to the mesenteric attachment by a thin bridge of fibroadipose tissue. The mass is entirely covered by serosa. The bowel wall is not involved (5.5 cm from closest mucosal margin). The mass is soft, friable, with up to 0.1 cm cystic degeneration, broad areas of necrosis (30% of volume), and focal hemorrhage.

BLOCK SUMMARY:

C1- tangential mucosal intestinal margin.

C2- tumor in relation to bowel.

C3-C4- additional representative tumor including area of necrosis.

D. "Right tube and ovary". Received is a 192 gram, 10 x 8 x 7 cm cystic, papillary, hemorrhagic and focally necrotic tumor without recognizable ovary. The tumor surface is irregular, focally disrupted, with focal fibrous adhesions. The fallopian is difficult to identify. An attached elongated structure is reminiscent of fallopian tube or round ligament (block D1).

BLOCK SUMMARY:

D1- uninvolved end of elongated structure.

D2-D5- tumor.

D6- tumor in relation to fibrous adhesions.

E. "Left tube and ovary". Received is a 12.6 gram specimen consisting of ovary (2.5 x 1.5 x 1.5 cm), fallopian tube (5.5 cm long, 0.5 cm in diameter), and attached fibroadipose tissue. The ovary and tube are grossly unremarkable. No tumor is seen. Representative sections are submitted in blocks E1-E2.

F. "Uterus, cervix". Received is a 67 gram, 8 x 4 x 4 cm uterus. A 3 x 2.5 x 2.5 cm subserosal nodule is located at the uterine fundus. A 0.4 cm intramural leiomyoma is located in the corpus. The endometrium (up to 0.1 cm thick) and myometrium (up to 1.8 cm thick) are unremarkable. The cervix is grossly unremarkable. The serosa is otherwise smooth.

BLOCK SUMMARY:

F1- anterior cervix.

F2- posterior cervix.

F3- anterior endomyometrium.

[page 2 of 3]
F4- posterior endomyometrium.
F5- fundic nodule.

G. "Pelvic peritoneum". Received is a 1.8 x 1 x 1 cm fragment of partially serosal covered fibroadipose tissue. No tumor is seen. The specimen is entirely submitted in block G1.

H. "Left pelvic side wall tumor". Received is a 5 x 3 x 2 cm specimen consisting of a 3 x 2.5 x 2 cm firm, white, tumor with lobular, focally yellow, hemorrhagic cut surface which is largely covered by serosa and exhibits a small amount of attached adipose tissue. Representative sections are submitted in blocks H1-H2.

I. "Cul de sac". Received is a 5 x 4 x 2.5 cm specimen consisting of a 4 x 2.5 x 2 cm firm, white, focally necrotic, irregular mass with extension into the surrounding fibroadipose tissue. Part of the specimen is covered with serosa which appears to be focally disrupted (block I1). Representative sections are submitted in blocks I1-I3.

J. "Perirectal tissue". Received is a 3.5 x 2 x 1.8 cm fragment of partially serosal covered tissue with a 1 x 0.5 x 0.5 cm area of tan firmness. Representative sections are submitted in block J1.

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: Hysterectomy and bilateral salpingo-oophorectomy, omentectomy, small bowel resection, multiple biopsies.

PATHOLOGIC STAGE: [REDACTED]: pT3c pNX pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this [REDACTED] required for accreditation by the [REDACTED] stage is based solely upon the current tissue [REDACTED] being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "LEFT GUTTER" (BIOPSY):

POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA.

B. "OMENTUM" (BIOPSY):

FIBROADIPOSE TISSUE, NEGATIVE FOR MALIGNANCY.
TWO LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/2).

C. "OMENTAL TUMOR WITH SMALL BOWEL" (EXCISION):

POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA (6.5 CM).
SMALL BOWEL MARGINS FREE OF TUMOR.

D. "RIGHT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

[page 3 of 3]
SEROUS ADENOCARCINOMA OF THE OVARY, SEE COMMENT.

FIGO GRADE: 3 OF 3 (POORLY DIFFERENTIATED).

TUMOR SIZE: 10 X 8 X 7 CM.

FALLOPIAN TUBE: NOT IDENTIFIED.

E. "LEFT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

OVARY AND FALLOPIAN TUBE, NO EVIDENCE OF MALIGNANCY.

F. "UTERUS, CERVIX" (HYSTERECTOMY):

UTERUS, 67 GRAMS

ENDOMETRIUM: ATROPHIC

MYOMETRIUM: LEIOMYOMA (0.4 CM), AND ADENOMYOSIS.

CERVIX: NO PATHOLOGIC DIAGNOSIS.

SEROSA: POSITIVE FOR METASTATIC SEROUS ADENOCARCINOMA (3 CM).

G. "PELVIC PERITONEUM" (BIOPSY):

NEGATIVE FOR MALIGNANCY.

H. "LEFT PELVIC SIDEWALL TUMOR" (BIOPSY):

POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA.

I. "CUL DE SAC" (BIOPSY):

POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA.

J. "PERIRECTAL TISSUE" (BIOPSY):

POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

COMMENT:

The tumor has large areas of transitional differentiation in both the ovary and in metastatic foci, although the underlying cell type is clearly serous. Very poorly differentiated serous carcinomas frequently develop a transitional cell morphology.

Performed by:

Source: NCI Genomic Data Commons file b8808241-e5af-46be-8a95-af1ca75ba98d (TCGA-29-2429.09804C6E-B6F3-482F-A23E-A4EFA84F2AB7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).